Surgical pathology report (de-identified scan), TCGA case TCGA-26-A7UX, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-A7UX-01B (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation / Department of Pathology

Case Type: Surgical

SPECIMEN(S) SUBMITTED / PROCEDURES ORDERED

A. Brain tumor A. Frozen Section Charge

A. Frozen Section Charge, Additional Block(s) B. Brain tumor

B. Glial Fibrill. Acid Prt B. P53 Protein B. Isocitrate dehydrogenase 1

B. KI-67, Nuclear Antigen, Mib1 B. Frozen Section Charge

CLINICAL HISTORY: year-old male, here for left craniotomy for tumor.

ICD-O-3

DIAGNOSIS:

A. Brain tumor, left frontal, craniotomy:

Glioblastoma multiforme (WHO Grade IV)

Glioblastoma Multiforme
9448/3

Site ^{CSCF} Brain NOS C71.9

B. Brain tumor, left frontal, craniotomy:

Glioblastoma multiforme (WHO Grade IV)

Path
④ Brain, frontal lobe C71.1

COMMENT: The neoplasm is best represented in specimen B, which shows a

JW 10/4/13

highly infiltrative glioma with focally high cellularity, mitotic

activity, and pseudopalisading necrosis. Extensive necrosis is present

in specimen A with only focal perivascular viable tumor. The results of

immunohistochemical studies, summarized below, support the diagnosis.

NEUROPATHOLOGY TUMOR SUMMARY

Tumor Site

Brain / Cerebrum

Frontal

Laterality: Left

Procedure

[page 2 of 3]
Open biopsy

Tumor

Glioblastoma (WHO grade IV)

Ancillary studies

Glioma ancillary studies

p53 IHC: Weakly positive: 5%

IDH-1 IHC: Negative

Ki-67 (MIB-1) IHC: Positive: 40%

Other (specify)

GFAP is strongly immunoreactive in tumor cells and cell processes.

GROSS DESCRIPTION: Received the following specimen(s) in the Department of Pathology, labeled with the patient's name and hospital #

A. Brain tumor

B. Brain tumor

A. The specimen is received fresh, designated "Brain tumor" and consists of a 1.5 x 1.0 x 0.5 cm aggregate of pale yellow-tan, bloody soft tissue. Representative sections are submitted for frozen section.

The resulting intraoperative diagnosis is "Extensive necrosis of the focal viable tumor. Frozen tissue is resubmitted for permanent processing in cassettes FSA1 and FSA2. The remaining tissue is submitted entirely in cassette A3.

B. The specimen is received fresh, designated "Brain tumor" and consists of a 2.5 x 1.5 x 0.5 cm aggregate of yellow-tan to pink-tan, bloody soft tissue. A representative sampling of the specimen is submitted for frozen section. The resulting intraoperative diagnosis is "Malignant glioma," per Dr. Frozen tissue is resubmitted for

[page 3 of 3]
permanent processing in cassette FSB1. A representative sampling is submitted to the tumor bank. The specimen is otherwise submitted entirely in cassettes B2 and B3. "I, or my qualified designee, performed the gross examination. I have personally reviewed the gross description and performed a microscopic examination on all referenced material. I have personally issued this report on the basis of the gross and microscopic findings."

Note: Test systems have been developed and their performance characteristics determined by Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Pathologist

HI/AA Discrepancy		✓

Source: NCI Genomic Data Commons file 659224dd-b521-4a40-9dbc-4c89323e946c (TCGA-26-A7UX.616868BB-6EDC-40F1-984B-95F279A7D60E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).